Surgical pathology report (de-identified scan), TCGA case TCGA-FP-7829, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-7829-01A (Primary Tumor).

[page 1 of 5]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

A) PARAESOPHAGEAL TISSUE, BIOPSY:

1. Negative for malignancy
2. Benign fibroadipose tissue identified only

B) ESOPHAGUS, DISTAL, AND PROXIMAL STOMACH, LAPAROSCOPIC DISTAL ESOPHAGECTOMY AND PROXIMAL GASTRECTOMY:

1. Invasive adenocarcinoma, moderately-differentiated (grade 2 of 4), mucinous type, characterized by:
- a. Formation of a 7.5 x 7.0 x 1.6 cm near circumferential polypoid mass at the gastroesophageal junction
- b. The adenocarcinoma invades through the muscularis propria to involve the paraesophageal fat and extends into the wall of the esophagus 2.5 cm from the GE junction and into the wall of the stomach 5.2 cm from the GE junction
- c. Angiolymphatic space invasion is identified
- d. Adenocarcinoma is present extending to the distal gastric margin (predominantly submucosal extent). The proximal and radial margins are negative for malignancy
2. Metastatic adenocarcinoma is identified in multiple (two) paraesophageal lymph nodes (twelve paraesophageal lymph nodes identified; five perigastric lymph nodes identified)
3. See staging summary

C) STOMACH, DESIGNATED NEW GASTRIC MARGIN, EXCISION:

1. Invasive moderately-differentiated adenocarcinoma, predominantly submucosal extension, is identified in the resection specimen
- a. The distal margin is negative for adenocarcinoma by less than 0.1 cm
- b. See comment
2. Gastrointestinal stromal tumor, 0.4 cm in greatest dimension, arising from the muscularis propria
- a. Nodule is hyalinized and focally calcified
- b. Immunohistochemistry for smooth muscle actin and Kit support the above diagnosis

D) ESOPHAGUS, ANASTOMOSIS RING PROXIMAL:

1. Full-thickness portions of esophagus identified
2. Negative for malignancy

E) STOMACH, ANASTOMOSIS RING DISTAL:

1. Full-thickness portion of stomach wall
2. Negative for malignancy

F) STOMACH, DESIGNATED PORTION OF, EXCISION:

[page 2 of 5]
1. Portions of benign gastric tissue
2. Negative for malignancy

COMMENT

In specimen C, the follow-up new gastric margin, microscopic foci of adenocarcinoma are present in the [REDACTED] stained permanent section from the distal resection margin sample. This slide represents deeper levels into paraffin-embedded tissue block and is therefore away from the true en face margin, relative to the prepared frozen section. The original frozen section slides were reviewed and no discrete malignant cells were identified. The nodule identified in the serosa at time of frozen section most likely represents the GIST identified on permanent sections. The submucosa, immediately adjacent to the GIST, is positive for adenocarcinoma and is present by direct extension from the primary lesion.

Findings of this case were discussed by [REDACTED]

on [REDACTED]

GASTROESOPHAGEAL JUNCTION CANCER STAGING PARAMETERS***

Per AJCC 7th edition tumors involving the GE junction and/or the proximal 5 cm of stomach are staged using esophageal cancer staging principles

Final TNM: pT3N1M0

stage: IIIA

MACROSCOPIC

PROCEDURE

Esophagogastrectomy

SPECIMEN TYPE

Esophagus, Proximal stomach

TUMOR SITE

Gastroesophageal junction

RELATIONSHIP OF TUMOR TO ESOPHAGOGASTRIC JUNCTION

Tumor midpoint is located at the esophagogastric junction ([REDACTED])

2)

TUMOR SIZE

Greatest dimension: 7.5 cm; Additional dimensions: 7 X 1.6 cm

MICROSCOPIC

HISTOLOGIC TYPE

Adenocarcinoma

HISTOLOGICAL GRADE

[REDACTED] (Moderately differentiated) of G4

Mucinous (>50% of lesion consisting of mucin)

TUMOR EXTENSION

Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)

MARGINS

Proximal Margin:

Normal squamous (no Barrett's esophagus, dysplasia, or malignancy)

Distal Margin:

Uninvolved by invasive carcinoma (following re-excision)

Circumferential Margin:

Uninvolved by invasive carcinoma

LYMPHATIC / VASCULAR INVASION

Present

BACKGROUND MUCOSA

Barrett's esophagus (esophageal goblet cells)

TREATMENT EFFECT

[page 3 of 5]
[REDACTED]

No prior treatment [REDACTED]

ADDITIONAL PATHOLOGIC FINDINGS

Intestinal metaplasia (Barrett's esophagus): Present
Dysplasia: High grade

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor invades adventitia)

REGIONAL LYMPH NODES

pN1. (Regional lymph node metastasis involving 1 to 2 nodes)

Total nodes: 17

Total positive nodes: 2

Maximum size of nodal metastasis: 0.1 cm

DISTANT METASTASIS

pM0. (Not applicable)

PATHOLOGIC STAGE Summary

Final TNM: pT3N1M0

[REDACTED] stage: IIIA

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

[REDACTED]

CLINICAL INFORMATION

This is a [REDACTED] male patient who presented with iron deficiency anemia and on diagnostic upper endoscopy was noted to have a mass present at the gastroesophageal junction. Preoperative biopsy revealed a positive result of invasive adenocarcinoma, moderately-differentiated (grade 2 of 4) that was involving gastric cardia-type mucosa.

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Paraesophageal tissue

Labeled "paraesophageal tissue" consists of a single 0.6 cm portion of fibrofatty tissue containing no grossly identifiable lymph nodes. The specimen is entirely submitted in one cassette.

B) SOURCE: Distal esophagus and stomach

Labeled "distal esophagus proximal stomach" consists of a partial gastroesophagectomy. The specimen consists of a 7 x 3 cm portion of esophagus and 10 x 9 x 3 cm portion of stomach. The specimen is opened revealing a polypoid near circumferential mass at the GE junction extending both into the esophagus by 2.5 cm and into the stomach for 5.2 cm. The overall dimensions of the tumor and suspicious surrounding mucosa are 7.5 x 7 cm. The tumor is grossly 3 cm from the nearest staple line. Note that an additional margin in this area was taken as specimen B. The remainder of the esophageal mucosa is shiny, tan-white with no gross evidence of Barrett's. The remainder of the gastric mucosa is granular with only a mild rugal pattern. The proximal resection margin is submitted on chuck #1 with the distal margin closest to the tumor on chuck #2.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Proximal margin negative. Distal margin possible vascular invasion" is rendered by [REDACTED]

[REDACTED]

On cut section, the tumor measures up to 1.6 cm in thickness and extends through the muscularis and abuts the serosa and may focally extend into the attached perigastric and periesophageal fat. The esophageal fat is searched revealing nine tan-white, 0.1-0.6 cm lymph nodes.

[REDACTED]

[page 4 of 5]
[REDACTED]

The gastric fat is searched revealing five, 0.1-0.7 cm lymph nodes.

[REDACTED]

Note: The remainder of the serosal surface of the stomach is unremarkable with no additional lesions.

Tissue is taken for possible ancillary studies.

A photograph is taken.

Representative sections are submitted in 25 cassettes labeled:

- BFS1. Frozen section, proximal margin
- BFS2. Frozen section, closest distal margin to gross tumor
- 3-5. Full thickness tumor to serosa and adjacent esophagus
- 6-8. Full thickness tumor and normal-appearing esophagus
- 9. Tumor and adjacent gastric mucosa
- 10. Edge of tumor
- 11-13. Random gastric mucosa
- 14. Additional distal margin, removed from tumor
- 15. Proximal esophageal mucosa
- 16-21. Remainder of esophageal fat
- 22. Five esophageal lymph nodes
- 23. Four esophageal lymph nodes
- 24. Two gastric lymph nodes, one inked yellow and bisected
- 25. Three gastric lymph nodes

C) SOURCE: New gastric margin

Received fresh labeled "new gastric margin" consists of an oriented stapled portion of stomach measuring 4 x 2.4 x 2 cm. The staple line at the new margin is taken en face and submitted on chuck #1 for frozen section diagnosis.

A surface yellow-tan, 0.4 cm nodule is seen on the serosa which is 2.5 cm from the new margin, and is entirely submitted on chuck #2 for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Final distal margin negative. Nodule on serosa is positive for adenocarcinoma" is rendered by [REDACTED]

Note: This specimen is reapproximated to the original specimen B and the new final distal gastric margin is now 7 cm grossly from the tumor.

The specimen is opened revealing a rugosed mucosa throughout with no masses or lesions. The minimal attached gastric fat is searched revealing no identifiable lymph nodes. No margin remains on this specimen. Representative sections of the mucosa are submitted in cassettes 3-5.

[REDACTED]

D) SOURCE: Anastomosis ring, proximal

Labeled "anastomosis ring proximal" consists of a ring of tan-pink mucosa received on a anastomosis device. It measures 0.6 cm in length and 1.5 cm in diameter. The ring displays tan-pink mucosa with no mass or lesion. Ring is sectioned and entirely submitted in a single cassette.

E) SOURCE: Anastomosis ring, distal

Labeled "anastomosis ring distal" consists of a tan-pink unoriented extensively stapled and sutured portion of mucosa measuring 0.8 cm in length x 1 cm in diameter. The mucosa is granular with no discrete mass or lesion. It is entirely submitted in a single cassette.

[REDACTED]

[page 5 of 5]
[REDACTED]

F) SOURCE: Stomach, portion

Labeled "portion of stomach" consists of an unoriented 3 x 1 x 1 cm strip of mucosa that is extensively stapled and sutured. The mucosa is granular and otherwise unremarkable. The strip of mucosa is removed from the staples and entirely submitted in a single cassette.

This case is accessioned in [REDACTED].

[REDACTED]

MICROSCOPIC

A-F) The microscopic appearance substantiates the diagnosis. Dictation by:

[REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL ([REDACTED]) - Lab and Collection Information

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL ([REDACTED]) - Order Result History Report.

Lab Status

Order Complete [3]

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Lab Information

Lab

Order Details

Parent Order ID

Child Order ID

Entry Date

Specimen Information

Specimen Source

Collection Date

Collection Time

Other

Audit Trail

[REDACTED]

MyChart Status:

This result is currently not released to MyChart.

Order

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 71af0db5-035f-484b-ab06-a868580eb853 (TCGA-FP-7829.7ADE7A91-922A-4ABB-A80C-AA2B70E438D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).